Surgical pathology report (de-identified scan), TCGA case TCGA-BR-8361, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-8361-01A (Primary Tumor).

[page 1 of 4]
	Case ID	Gross Description	Microscopic Description

[page 2 of 4]
Diagnosis Details	Comments	Formatted Path Report
		STOMACH TISSUE CHECKLIST Specimen type: Gastrectomy Tumor site: Fundus Tumor size: 10 x 10 x 4 cm Tumor features: None specified Histologic type: Adenocarcinoma Histologic grade: Poorly differentiated Tumor extent: Adjacent structures (specify) - Transverse colon Lymph nodes: 6/10 positive for metastasis (Intraabdominal 6/10) Lymphatic invasion: Not specified Venous invasion: Not specified Perineural invasion: Not specified Margins: Uninvolved Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: None

[page 3 of 4]
	ID	Excision Date

[page 4 of 4]
Laterality

Source: NCI Genomic Data Commons file 505ec776-72a2-4756-aa10-f161f138cfb4 (TCGA-BR-8361.B8966001-4E75-4D0E-B31D-F2B283D0E326.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).